Surgical pathology report (de-identified scan), TCGA case TCGA-AF-6136, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-6136-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Rectosigmoid colon
- B. Proximal colon
- C. Distal donut

CLINICAL NOTES

PRE-OP DIAGNOSIS: Rectal cancer.

GROSS DESCRIPTION

A. Received in fresh subsequently fixed in formalin labeled "rectosigmoid colon" is a 19 cm. long portion of colon which is stapled at one end (possibly proximal) inked blue and the opposite end is opened and inked black. Retroperitoneal reflection is located 7.5 cm. from the distal end. The specimen is otherwise covered with pink-tan, glistening serosa and abundant yellow lobular fat. The specimen is opened to show pink-tan glistening mucosa with an average circumference of 5.4 cm. There is a 4.5 x 3.8 x 1.0 cm. tumor coming to within 1.5 cm. from of the distal margin. The cut surface of the tumor shows invasion into the muscularis propria, coming to within 0.3 cm. of the radial margin. This radial margin is inked orange. No other discrete gross lesions are identified. Samples are taken for tissue procurement. Lymph nodes are grossly identified in the fat, measuring up to 0.9 cm. in greatest dimension. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: #1 - Representative luminal margins; 2-5 - representative sections of tumor which includes tumor to radial margin; 6-15 - whole lymph nodes. RS-15. [REDACTED]

B. Received fresh and subsequently fixed in formalin, labeled "proximal colon" is a 9.5 cm portion of colon, which is opened at one end inked blue and the opposite end is inked black and stapled. The serosa is pink-tan smooth glistening partially covered with yellow lobular fat. The specimen is opened to show pink-tan smooth glistening mucosa, which is slightly flattened, having an average circumference of 4.5 cm. No other discrete gross lesions are identified. The specimen fat is palpated to identify few lymph nodes. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: 1 - Representative luminal margins, 2 - representative sections are remainder of the specimen; 3 - possible . RS-3.

C. Received in formalin labeled "distal donut" is a 2.5 x 2.2 x 1.2 cm pink tan rubbery annular tissue fragment partially covered by pink tan smooth glistening mucosa. The tissue fragment shows no other discrete gross lesions identified and is entirely submitted in one cassette. AS-1. [REDACTED]

MICROSCOPIC DESCRIPTION

This tumor is a moderately differentiated adenocarcinoma with quite extensive invasion. It extends through the

[page 2 of 2]
bowel wall and sends tongues of tumor into pericolic fat and incites a scirrhous reaction. Because of the propensity to send these narrow tongues of infiltrating tumor out into the fat, there is minimal extension to the radial margin. Also tumor nests are present within soft tissue (blocks 11, 13). Lymphatic invasion is noted in the pericolic soft tissue (block number 11). Invasion of an artery is also noted. Please see the template below

Histologic type: Adenocarcinoma
Histologic grade: Moderately differentiated
Primary tumor (pT): pT3
Proximal margin: Negative for tumor
Distal margin: Tumor for tumor
Circumferential (radial) margin: Minimally positive
Distance of tumor from closest margin: Tumor is present to within 1.5 cm. of the distal margin and is present at the radial margin
Vascular invasion: Rare lymphatic and arterial invasion noted
Regional lymph nodes (pN): 52 lymph nodes present, 2 of which are positive for metastatic disease, 2/52, pN1b
Non-lymph node pericolic tumor: present
Distant metastasis (pM): Cannot be assessed
Other findings: None

B and C. Microscopic examination performed.

5, 4, 3

DIAGNOSIS

- A. Rectosigmoid colon, segmental resection - Segment of colon with moderate differentiated adenocarcinoma extending into pericolic fat and minimally to radial margin of resection. Metastatic disease present to 2 of 52 lymph nodes, 2/52. Lympho-vascular space invasion present.
- B. Proximal colon, segmental resection - Segment of colon, no significant pathology.
Five additional lymph nodes all negative for metastatic disease, 0/5.
- C. Distal donut, excision - Stapled portion of colonic tissue, no significant pathology.
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 06ca4f95-0aa8-4333-a7d2-858c45252a63 (TCGA-AF-6136.18CAACB8-C226-49AF-9574-F1A9A9BDEDAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).